CCDI case PBCNMG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0d44e6e6-76c3-4a60-a7ad-f2d602b65859

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.4 years (1,607 days).

Biospecimens (3 samples)
- Sample 0DVZ0U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZ15: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVZ18: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
